Gene-level copy-number profile of tumor specimen TCGA-ZF-A9RM-01A from TCGA case TCGA-ZF-A9RM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 70.2 years (25,642 days).
Specimen TCGA-ZF-A9RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.84146ddc-4dec-467d-9181-c02b88fc5c98.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-A9RM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/533f75ed-4690-4b11-9bd9-a7c68a410cb8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,180; copy number 2: 5,804; copy number 3: 18,530; copy number 4: 30,120; copy number 5: 2,140; copy number 6: 1,459; copy number 7: 25; copy number 8: 110; copy number 10: 44; copy number 11: 46; copy number 12: 59; copy number 13: 27; copy number 14: 56; copy number 15: 103; copy number 17: 43; copy number 18: 6; copy number 19: 14; copy number 20: 18; copy number 21: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-A9RM-01A-11D-A38F-01): tumor purity 0.82, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:68,113,706–68,422,196, 6 genes: AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.
- chr18:7,566,782–8,406,861, 7 genes (within-gene range 0–1): PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 437 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–10,054,866, 152 genes, copy number 12–20 (broad region; genes not listed).
- chr12:108,738,484–118,136,026, 217 genes, copy number 10–21 (within-gene range 2–21) (broad region; genes not listed).
- chr12:119,959,424–120,094,494, 4 genes, copy number 19: RPL35AP30, BICDL1, Metazoa_SRP, AC004812.1.
- chr12:124,513,222–124,638,444, 10 genes, copy number 19: AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4.
- chr12:126,094,112–126,177,632, 4 genes, copy number 17–21 (within-gene range 2–21): LINC02359, AC005858.2, AC005858.3, AC005858.1.
- chr12:126,191,151–128,123,103, 50 genes, copy number 14 (within-gene range 2–14): AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC025160.1, AC087894.3, AC087894.2, AC087894.1, LINC02393, LINC00507, LINC00508, LINC02441, AC140121.1, LINC02369, LINC02368.

Autosomal genes at a single copy (total copy number 1): 91. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
